Gene-level copy-number profile of tumor specimen C3L-05983-02 from CPTAC case C3L-05983, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 52.8 years (19,298 days).
Specimen C3L-05983-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6a30b162-c8a0-4640-b53c-4d7492197ba8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-05983-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/92db58f5-eaf9-4f90-9358-59de5e71efe7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 86; copy number 1: 4,105; copy number 2: 40,001; copy number 3: 10,985; copy number 4: 2,636; copy number 5: 817; copy number 6: 61; copy number 7: 6; copy number 8: 61; copy number 9: 1; copy number 11: 41; copy number 24: 18; copy number 31: 13; copy number 37: 62; copy number 43: 17.

Homozygous deletions (total copy number 0; autosomes only): 86 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:97,081,098–97,100,874, 4 genes: GPAT2P2, FAHD2B, AC018892.3, RN7SL313P.
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr7:111,091,006–111,125,454, 1 gene (within-gene range 0–2): LRRN3.
- chr8:7,926,337–8,049,267, 12 genes: ZNF705B, DEFB108A, FAM66E, AC130365.1, USP17L8, USP17L3, DEFB109C, FAM90A11P, FAM90A24P, FAM90A12P, OR7E96P, AC105233.1.
- chr8:8,086,022–8,116,949, 4 genes: AC105233.2, MIR548I3, RPS3AP31, SNRPCP17.
- chr9:40,992,249–41,218,410, 2 genes (within-gene range 0–2): FRG1HP, PGM5P2.
- chr9:41,061,290–42,714,539, 47 genes (within-gene range 0–2): AL353763.1, BX255923.1, BX255923.2, FOXD4L6, CBWD6, MIR4477A, RNA5SP530, AL845472.1, PTGER4P2-CDK2AP2P2, CDK2AP2P1, MYO5BP1, AL354718.2, CDRT15P6, AL354718.1, AL591926.3, SNORA70, RN7SL565P, AL591926.7, AL591926.6, AL591926.5, AL591926.2, FAM242F, Y_RNA, AL591926.1, AL591926.4, AL162731.1, CNTNAP3B, RBM17P3, CR788268.1, RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6, BX088651.4, BX088651.1, BX088651.2, FGF7P5, BX088651.3, FGF7P4, BX664718.1.
- chr9:64,473,040–64,889,063, 13 genes: CR769776.1, CNN2P3, GXYLT1P6, AL773524.1, AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2, BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P.
- chr20:14,547,184–14,547,623, 1 gene (within-gene range 0–1): RNF11P2.
- chr20:14,933,843–14,935,363, 1 gene (within-gene range 0–1): AL138808.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,097 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,548,756–248,565,299, 3 genes, copy number 5: AC098483.1, OR2AS1P, OR2T29.
- chr2:37,167,820–38,109,902, 19 genes, copy number 5 (within-gene range 4–5): SULT6B1, RPL31P16, CEBPZOS, CEBPZ, AC007390.1, NDUFAF7, PRKD3, AC007391.1, RNU6-939P, QPCT, RNU6-1116P, AC006369.1, CDC42EP3, AC006369.2, AC010878.1, LINC00211, RMDN2, RMDN2-AS1, CYP1B1.
- chr4:49,486,926–49,589,529, 12 genes, copy number 5: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr7:5,103,719–5,513,809, 12 genes, copy number 6 (within-gene range 4–6): OR10AH1P, ZNF890P, RNU6-215P, WIPI2, SLC29A4, TNRC18, AC093620.1, AC092171.1, AC092171.4, AC092171.3, AC092171.5, FBXL18.
- chr8:127,289,817–127,636,867, 5 genes, copy number 5–7: CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1.
- chr8:139,727,725–141,367,286, 27 genes, copy number 5: TRAPPC9, AC021744.1, C8orf17, AC040978.1, PEG13, AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD, PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20.
- chr8:143,213,218–145,066,685, 127 genes, copy number 5 (broad region; genes not listed).
- chr13:65,309,855–114,337,626, 550 genes, copy number 5–6 (broad region; genes not listed).
- chr16:11,797,468–11,851,580, 3 genes, copy number 5: AC010654.1, BCAR4, RSL1D1.
- chr16:31,952,160–32,310,555, 22 genes, copy number 5–7: AC034105.5, AC034105.1, AC034105.4, AC142381.3, AC142381.4, IGHV1OR16-1, AC142381.1, IGHV1OR16-3, IGHV3OR16-9, HERC2P4, AC142381.2, AC133485.7, AC133485.6, AC133485.5, AC133485.4, ABHD17AP8, AC133485.1, AC133485.3, TP53TG3D, AC133485.2, AC140878.1, AC133548.2.
- chr16:32,439,069–32,478,250, 4 genes, copy number 6–9: PABPC1P13, AC138915.3, AC138915.1, ABCD1P3.
- chr17:39,461,486–41,812,604, 151 genes, copy number 11–43 (broad region; genes not listed).
- chr17:65,528,563–69,553,865, 92 genes, copy number 6–8 (broad region; genes not listed).
- chr20:31,257,664–32,858,751, 70 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,311. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
